Somatic mutation profile of tumor specimen TCGA-KL-8345-01A (aliquot TCGA-KL-8345-01A-11D-2310-10) from TCGA case TCGA-KL-8345, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 75.0 years (27,412 days).
Specimen TCGA-KL-8345-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a126924-efa4-47a7-bf38-4d0d2fca32d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KL-8345-11A (Solid Tissue Normal), aliquot TCGA-KL-8345-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5872a817-7fa1-4233-bdf4-fa63d280bdbc

The open-access MAF lists 28 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 18, Silent 5, Splice Site 3, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGBL4 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 59/75 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779103173, COSV61890672; called by muse, mutect2, varscan2
- CALHM6 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as rs1392090799, COSV100889464; called by muse, mutect2, varscan2
- COMMD6 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs143172831, COSV63322471; called by muse, mutect2, varscan2
- CORO7 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1245147090, COSV52032910, COSV99228030; called by muse, mutect2
- CSF2RB | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs773437114, COSV99454300; called by muse, mutect2, varscan2
- CXXC1 | c.350A>C p.D117A | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99497008; called by muse, mutect2, varscan2
- DSPP | c.1940G>T p.S647I | Missense Mutation (SNP) | VAF 114/267 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV99217805; called by muse, mutect2, varscan2
- EXOC1 | c.769C>T p.H257Y | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100637974; called by muse, mutect2, varscan2
- FAT4 | c.12149T>C p.L4050P | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100629732; called by muse, mutect2, varscan2
- GAB4 | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as rs373667129; called by muse, mutect2, varscan2
- IGFBP5 | c.277C>A p.L93M | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV99288901, COSV99289114; called by muse, mutect2, varscan2
- MAG | c.1390G>T p.E464* | Nonsense Mutation (SNP) | VAF 21/49 reads (43%) | catalogued as COSV100728011; called by muse, mutect2, varscan2
- MTCH2 | c.370-2A>G p.X124_splice | Splice Site (SNP) | VAF 4/70 reads (6%) | catalogued as COSV100207085; called by muse, mutect2
- NOP9 | c.1647+1G>A p.X549_splice | Splice Site (SNP) | VAF 24/45 reads (53%) | catalogued as COSV99351076; called by muse, mutect2, varscan2
- P3H4 | c.1102G>C p.E368Q | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT tolerated (0.41); PolyPhen benign (0.103); catalogued as COSV100821285; called by muse, mutect2, varscan2
- RGS12 | c.2427+1G>A p.X809_splice | Splice Site (SNP) | VAF 52/131 reads (40%) | catalogued as COSV100123237; called by muse, mutect2, varscan2
- SPAG17 | c.2810T>A p.L937H | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60459254; called by muse, mutect2, varscan2
- TAF1 | c.4049C>T p.P1350L (on ENST00000373790 / NM_138923.4; = p.P1371L on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV99336696; called by muse, mutect2, varscan2
- TJP2 | c.1602T>G p.F534L | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as rs913689505, COSV99601673; called by muse, varscan2
- TLK1 | c.1244C>A p.A415E | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.964); catalogued as COSV100688684; called by muse, mutect2, varscan2
- TTLL4 | c.1873C>T p.R625W | Missense Mutation (SNP) | VAF 58/82 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs370491335; called by muse, mutect2, varscan2
- VIPR2 | c.1178G>T p.R393L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100057958; called by muse, mutect2, varscan2
- PTEN | c.540_546del p.Y180* | Frame Shift Del (DEL) | VAF 21/32 reads (66%) | called by mutect2, pindel, varscan2
- ANK2 | c.6627G>A p.G2209= | Silent (SNP) | VAF 47/110 reads (43%) | catalogued as COSV100003503; called by muse, mutect2, varscan2
- DSCAM | c.3396C>T p.L1132= | Silent (SNP) | VAF 36/81 reads (44%) | catalogued as COSV101261253, COSV68021839; called by muse, mutect2, varscan2
- GRAMD1C | c.756A>G p.E252= | Silent (SNP) | VAF 8/142 reads (6%) | catalogued as rs1202755363, COSV100822960; called by muse, mutect2
- KIDINS220 | c.4506C>T p.L1502= | Silent (SNP) | VAF 74/100 reads (74%) | catalogued as COSV99876270; called by mutect2, varscan2
- TTN | c.43431T>C p.D14477= (on ENST00000591111; = p.D7053= on NM_003319.4) | Silent (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
